FM case AD831 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/5b32e0c8-2f14-4fff-9ac3-7ebe96b9e076

Male, 70.9 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the prostate gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
